Somatic mutation profile of tumor specimen 0DNKZI from CCDI case PBCBUL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.1 years (1,116 days).
Specimen 0DNKZI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c65a1a9-68c8-4b57-9524-62b6808b2f81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNKZD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f73b78d-f04d-4418-aac7-993814288cc6

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 80/471 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.695G>A p.R232H (on ENST00000326724 / NM_001080395.3; = p.R129H on NM_004920.2) | Missense Mutation (SNP) | VAF 227/476 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200466748, COSV58686257; called by muse, mutect2, varscan2
- DCAF12L2 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100758472; called by muse, mutect2
- DEFB134 | c.174C>A p.C58* | Nonsense Mutation (SNP) | VAF 199/421 reads (47%) | catalogued as COSV101198486; called by muse, mutect2, varscan2
- MEFV | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 84/521 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.925); catalogued as rs574055513, COSV54828554, COSV99561253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF212 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs370043717; called by muse, mutect2, varscan2
- LIMCH1 | c.533_536dup p.Y179* | Nonsense Mutation (INS) | VAF 194/484 reads (40%) | called by mutect2, varscan2
- TNS4 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 184/396 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0.115); called by muse, mutect2, varscan2
